Surgical pathology report (de-identified scan), TCGA case TCGA-60-2721, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2721-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. LEVEL 4 R LYMPH NODE
B. LEVEL 7 LYMPH NODE
C. LEVEL 4L LYMPH NODE
D. RIGHT UPPER LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Level 4R lymph node - lymphoid tissue, negative for carcinoma

FSB: Level 7 lymph node - lymphoid tissue, negative for carcinoma

FSC: Level 4L lymph node - lymphoid tissue, negative for carcinoma

FSD: Right upper lobe: Bronchial margin-Negative for tumor.

GROSS DESCRIPTION:**A. LEVEL 4R LYMPH NODE**

Received fresh and labeled with the patient name [REDACTED] designated "A - level 4R lymph node", are multiple fragments of red-tan soft tissue measuring 0.8 x 0.8 x 0.2 cm in aggregate. The entire specimen is submitted for frozen section in cassette FSA1.

B. LEVEL 7 LYMPH NODE

Received fresh and labeled with the patient name [REDACTED] designated "B - level 7 lymph node", are multiple fragments of red-tan soft tissue measuring 1.8 x 1.0 x 0.3 cm in aggregate. The entire specimen is submitted for frozen section in cassette FSB1.

[page 2 of 3]
[REDACTED]

C. LEVEL 4L LYMPH NODE

Received fresh and labeled with the patient name [REDACTED] designated "C - level 4L lymph node", are 2 fragments of red-tan soft tissue measuring 0.7 x 0.3 x 0.2 cm in aggregate. The entire specimen is submitted for frozen section in cassette FSC.

[REDACTED]

D. RIGHT UPPER LOBE

Received fresh and labeled [REDACTED] d. right upper lobe" is a lobectomy specimen measuring 16 x 13 x 4 cm and weighing 239 gm. On the pleura, there is a 6.0 cm in length and 3.0 cm in width gray plaque. This region is inked. Dissection reveals a 5.1 x 4.2 x 3.2 cm mass which is 1.5 cm from the bronchial margin and 0.1 cm beneath the pleural surface. The remainder of the parenchyma has a red-tan coloration. A shaved section is taken of the bronchial margin and the bronchi are opened. They have a smooth tan appearance. Tissue is submitted for procurement. Representative sections are submitted as follows:

FSD1: frozen shaved section of bronchial margin

D2-D6: sections of mass in association with normal appearing parenchyma and pleura

D7: normal appearing parenchyma

D8: area of discoloration on pleural surface

D9: possible anthracotic lymph nodes

[REDACTED]

DIAGNOSIS:

A. LEVEL 4R LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

B. LEVEL 7 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

C. LEVEL 4L LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

D. RIGHT UPPER LOBE, LOBECTOMY:

- NON-KERATINIZING SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, TUMOR SIZE 5.1 X 4.2 CM

- BRONCHIAL MARGIN, NEGATIVE FOR TUMOR

- FOUR PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR TUMOR (0/4)

- SUBPLEURAL FIBROSIS AND OSSIFICATION

- SEE TEMPLATE

[REDACTED]

[page 3 of 3]
SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: D: RIGHT UPPER LOBE

Surgical Procedure: Lobectomy

Laterality: Right

Tumor Site: Upper lobe

Tumor Location: Central

Tumor Size: Greatest diameter: 5.1cm

Additional dimensions: 4.2cm x 3.2cm

WHO CLASSIFICATION

Squamous cell carcinoma

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 4

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 2

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1

Non-Neoplastic Lung: Emphysematous changes
subpleural fibrosis and osseous metaplasia

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 0 M X

Source: NCI Genomic Data Commons file b01bfad6-5737-4596-a68b-3bb39ba3c525 (TCGA-60-2721.1447D27E-C268-4BC6-8919-B13878F8E862.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).